PECGS case C083-000031 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/f03ff93c-3ffa-4afb-8dcb-6bac045da452

Demographics
Sex at birth: male; Age at index: 41 years; Year of birth: 1975; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 41.1 years (15,012 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: no.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000031_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000031_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
